Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72R, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72R-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number:

ICD O-3

Carcinoma, renal cell
chromophobe type 8/17/13

Site ② Kidney NOS 864.9

JW 8/9/13

Diagnosis:

A: Lymph node, left para-aortic, biopsy
- No metastatic carcinoma identified (0/1)

B: Lymph nodes, left para-aortic, removal
- No metastatic carcinoma identified (0/6)

C: Renal mass, left, partial nephrectomy

Tumor histologic type: Eosinophilic variant of chromophobe renal cell carcinoma

Sarcomatoid features: Not identified

Histologic grade: 1 (of 4, Fuhrman classification)

Tumor size: 6.0 cm

Tumor focality: Unifocal

Extent of invasion:

Extra-capsular invasion into perirenal adipose tissue: Not involved

Venous: Absent

Lymphatic: Absent

Surgical margins:

Renal parenchymal margin: Negative

Renal capsular margin: Negative

Perinephric adipose tissue margin: Negative

Adrenal gland: Not submitted

Lymph nodes: Separately submitted, see A and B above

Pathologic findings in non-neoplastic kidney: None

AJCC Stage: pT1b pN0

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 2 of 3]
Comment:

The neoplasm is comprised of sheets of cells with pleomorphic nuclei without nucleoli. The neoplastic cells have eosinophilic, granular cytoplasm with perinuclear clearing, and distinct cellular borders. Immunostains show reactivity for CK7 and CD117, with no reactivity for vimentin or RCC. There is focal cytoplasmic reactivity for colloidal iron. Morphologic and immunophenotypic findings support a diagnosis of eosinophilic variant of chromophobe renal cell carcinoma, and serve to exclude oncocytoma, conventional RCC, and type 2 papillary RCC.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. in

FSA1: Lymph node, left periaortic, biopsy
- No tumor seen

Drs. at

Frozen Section Pathologist: ,

Clinical History:

year-old female with possible T1B renal cell carcinoma.

Gross Description:

Received are three appropriately labeled containers. Container A is received fresh for frozen section, and additionally labeled "left periaortic lymph node." It holds a 1.9 x 1.2 x 0.5 cm lymph node candidate which is bisected and totally submitted in block FSA1,

Container B is additionally labeled "left para-aortic lymph node." It holds a 1.5 x 1.3 x 0.9 cm aggregate of tan to yellow fatty soft tissue fragments. Dissecting the fat reveals multiple lymph node candidates ranging from 0.3 to 1.2 cm in greatest dimension.

Block summary:

B1 - largest lymph node candidate, serially sectioned
B2,B3 - multiple lymph node candidates
Fat remains in the container.

Container C is additionally labeled "left renal mass." It holds a partial nephrectomy specimen (6.2 x 6.0 x 4.3 cm, 78 grams).

[page 3 of 3]
The external surface is a smooth tan renal capsule with no disruptions. The capsule is inked black and the renal parenchymal margin is inked blue. The specimen is serially sectioned to reveal an encapsulated, roughly spherical mass that comprises the majority of the specimen (6.0 x 4.5 x 4.0 cm). The mass has a heterogeneous tan/brown cut surface with numerous areas of necrosis and hemorrhage. The mass abuts and distorts the capsule, but does not appear to disrupt the renal capsule. The fibrous capsule of the mass extends to the renal parenchymal margin but does not appear to invade. Representative sections of the mass at the capsule are submitted in blocks C1 and C2, and representative sections of the mass at the renal parenchymal margin are submitted in blocks C3 and C4.

Source: NCI Genomic Data Commons file 7a65d3c3-c1f4-47c9-ba9a-ed9cec99b3dd (TCGA-UW-A72R.F0A3D7E1-CDAF-4BD4-8D55-3F129A9BAC21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).